Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A6EC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A6EC-06A (Metastatic).

ICD-O-3
Melanoma, malignant NOS
8720/3
Site: Axillary lymph
node C77.3
JW 6/25/13

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) Skin melanoma of the back post resection Metastasis to lymph nodes of the left axilla

Date of admission:

Material:

1) Material: axillary lymph nodes. Method of collection: Total organ resection

Histopathological diagnosis

Examination performed on:

Metastases of malignant melanoma in lymph nodes NO I/VIII. (8010/6 T-08710)*

* codes acc. to ICD-O-3 or SNOMED

Macroscopic description:

Two surgical specimens sized 11.8 x 8.4 x 5.4 cm and 8 x 5.5 x 1.1 cm.

Lymph nodes in the cross section. The largest lymph node sized: 6.5 x 5.8 x 4.7 cm.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file cba31d1f-94ca-4aba-b68f-9751c2f8fdef (TCGA-D9-A6EC.57FE7B94-1751-417D-8D31-25F06A952E71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).